Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A71R, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A71R-01A (Primary Tumor).

Result Type: Surgical Pathology Report
Result Date:
Performed By:
Encounter Info:

Surgical Pathology Report

ICD-O-3
Carcinoma, papillary
renal cell 8260/3
Site @ Kidney NOS
C64.9
8/9/13

Surgical Pathology Report

DIAGNOSIS:

A. Left lower pole renal cyst wall: Benign renal cortical cyst. There is no evidence of malignant tumor.
B. Para-aortic lymph node, biopsy: Six lymph nodes negative for metastatic carcinoma.
C. Left renal mass, partial nephrectomy: Papillary renal cell carcinoma (see synoptic report below).
Procedure/laterality: Partial nephrectomy, left kidney.
Histologic type: Papillary renal cell carcinoma.
Nuclear grade (Fuhrman, 1-4): Nuclear grade 1 (of 4 grades).
Tumor size: 4.0 x 3 x 3 cm.
Tumor site: Lower pole.
Tumor focality: Unifocal.
Sarcomatoid features: Absent.
Tumor necrosis: Absent.
Microscopic tumor extension: Confined to renal parenchyma without extension into perinephric tissue, Gerota's fascia, renal sinus, renal vein, or collecting system.
Surgical margins: Negative for tumor.
Lymph-vascular invasion: Absent.
Periaortic lymph nodes: Negative for tumor (6 total).
Pathologic findings in nonneoplastic kidney: No diagnostic abnormalities.
Pathologic staging: pT1a, pN0.
Biorepository sample (if applicable): Not applicable.

CLINICAL INFORMATION:

Left renal mass

SPECIMEN(S):

A: Left lower pole renal cysts wall
B: Paraaortic lymph node
C: Left renal mass

A1 B1 B2 C1 C2 C3 C4 C5 C6

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled and "left lower pole renal cyst wall" is a portion of yellow and tan-brown fibrofatty tissue, 1.3 x 1.0 x 0.3 cm. Bisected and all submitted in one cassette (A1).

B. Received fresh labeled and "periaortic lymph nodes" is a portion of fibrofatty tissue, 5.0 x 4.0 x 1.5 cm. This tissue contains six possible lymph nodes that are from 0.6 cm to 2 cm. Submitted in two cassettes (B1 and B2). B1, five node B2, one bisected node.

C. Received fresh labeled and "left renal mass"
Procedure: Partial nephrectomy.
Specimen laterality: Left.

Tumor site: Lower pole.
Tumor size: 4.0 x 3.0 x 3.0 cm.
Tumor focality: Unifocal.
Gross extent of tumor:

Extension into perinephric tissue: Absent.
Extension beyond Gerota's fascia: Absent.
Extension into renal sinus: Absent.
Extension into renal vein: Absent.
Extension into collecting system: Absent.

Adrenal gland: Absent.

Gross Notes:

Gross tumor characteristics: Predominantly cystic, containing red-brown friable material with a rim of solid yellow-orange tissue.
Kidney weight: 45 grams with fat; 30 grams without fat.
Kidney dimensions: 6.0 x 4.0 x 3.0 cm.
Ureter dimensions: Not applicable.

Distance to margin focally

0.2-0.3 cm.

Inking details: Parenchymal margin black, peripheral perinephric fat margin blue.

Block summary for specimen C:

C1-4. Cystic tumor and adjacent normal kidney and parenchymal margin.

C5. Section corresponding to tissue submitted for research

C6. Peripheral perinephric fat margin.

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 20d9ba0b-10fa-4619-aa50-b346bd2989f3 (TCGA-SX-A71R.9E7F519D-947D-4A9E-96A2-ED94CF65E109.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).